Surgical pathology report (de-identified scan), TCGA case TCGA-99-8028, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-8028-01A (Primary Tumor).

[page 1 of 3]
Patient Name

MR#

Observation Date

Last Edited Date

SURGICAL PATHOLOGY

CASE:

Received Date:

Diagnosis

Lymph node, #5, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, #6, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, #7, excision:

- Two lymph nodes negative for malignancy (0/2).

Lymph node, #9, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, #8, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, #10, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #12, excision:

- Fragments of lymph node negative for malignancy.

Bronchial margin, excision:

- Negative for malignancy.

Lymph node, #11, excision:

- Fragments of lymph node negative for malignancy.

Lung, left upper lobe, lobectomy:

- Adenocarcinoma, moderately differentiated (2 cm); margin of resection is negative for malignancy; pleural surface is not involved.
- Two lymph nodes negative for malignancy (0/2).
- Pathologic stage: pT1a/N0/Mx.

(Electronically signed by)

Verified:

Clinical Information: The patient is a year old female with lung cancer.

Frozen Section Diagnosis

HFS1: Bronchial margin, biopsy:

- Negative for malignancy.

JFS1: Lung, left upper lobe, lobectomy:

- Non-small cell carcinoma.

[page 2 of 3]
Gross Description

Ten specimens are received in separate containers labeled with the patient's name and medical record number. The first specimen is also labeled "#5 lymph node". Received is a single irregularly shaped fragment of tan-yellow and black tissue measuring 1.0 x 0.9 x 0.5 cm in maximum gross dimension. The specimen is entirely submitted in cassette A1. The second specimen is also labeled "#6 lymph node". Received are two irregularly shaped fragments of tan-yellow and black tissue measuring 1.3 x 0.9 x 0.6 cm together. The specimen is entirely submitted in cassette B1. The third specimen is also labeled "#7 lymph node". Received is a single irregularly shaped fragment of tan-pink and black tissue measuring 1.4 x 1.0 x 0.4 cm in maximum gross dimension. The specimen is entirely submitted in cassette C1. The fourth specimen is also labeled "#9 lymph node". Received are two irregularly shaped fragments of yellow-tan tissue measuring 1.0 x 0.6 x 0.4 cm together. The specimen is entirely submitted in cassette D1. The fifth specimen is also labeled "#8 lymph node". Received is a single irregularly shaped fragment of tan-brown and black tissue measuring 0.8 x 0.5 x 0.3 cm in maximum gross dimension. The specimen is entirely submitted in cassette E1. The sixth specimen is also labeled "#10 lymph node". Received are two irregularly shaped fragments of tan-purple and black tissue measuring 1.7 x 1.1 x 0.6 cm together. The specimen is entirely submitted in cassette F1. The seventh specimen is also labeled "#12 lymph node". Received is a single irregularly shaped fragment of tan-purple and black tissue measuring 1.5 x 0.7 x 0.6 cm. The specimen is entirely submitted in cassette G1. The eighth specimen was originally received fresh for frozen section is now resubmitted for permanent section. It is also labeled "bronchial margin". Received at the time of frozen section was a 1.0 x 0.4 x 0.2 cm fragment of tan-red tissue. The specimen was entirely submitted at the time of frozen and is entirely resubmitted for permanent section. The ninth specimen is also labeled "#11 lymph node". Received is a single irregularly shaped fragment of tan and black tissue measuring 1.2 x 0.8 x 0.6 cm in maximum gross dimension. The specimen is entirely submitted in cassette I1. The tenth specimen was originally received fresh for frozen section and is now resubmitted for permanent section. It is also labeled "left upper lobe". Received is a lobectomy which measures 14.5 x 9.3 x 3.3 cm in maximum gross dimension. The pleural surface is purple, pink-tan and mottled. There is multifocal anthracotic pigment. At time of frozen section a 2.0 x 2.0 x 0.6 cm previously incised tan mass was identified. The mass appears to grossly abut the pleural surface. The mass is located approximately 2.5 cm to the nearest surgical stapled margin. The remainder of the specimen is serially sectioned to reveal a maroon-red parenchyma with anthracosis. No other mass lesions are noted. Representative sections are submitted. [REDACTED]

Block Summary

- A1- #5 lymph node, entirely submitted.
- B1- #6 lymph node, entirely submitted.
- C1- #7 lymph node, entirely submitted.
- D1- #9 lymph node, entirely submitted.
- E1- #8 lymph node, entirely submitted.
- F1- #10 lymph node, entirely submitted.
- G1- #12 lymph node, entirely submitted.
- H1 Bronchial margin, entirely submitted.
- I1- #11 lymph node, entirely submitted.
- J1- Tumor, frozen section.
- J2- Tumor in relation to pleural surface.
- J3- Radial section at nearest surgical stapled margin.
- J4- Vascular margin.
- J5-J6- Additional sections of tumor.
- J7- Uninvolved lung parenchyma.
- J8- Possible lymph node.

Microscopic Description

A microscopic examination has been performed. [REDACTED]

[page 3 of 3]
SP Synoptic Report

J: Thorax Lung SPECIMEN:

Lobe(s) of lung: Left upper

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY

SPECIMEN LATERALITY: Left

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 2.0 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

VASCULAR MARGIN: Uninvolved by invasive carcinoma

LYMPH NODES

PRIMARY TUMOR (pT): pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

Source: NCI Genomic Data Commons file 60207e24-6aa8-42f2-bbfc-e801c110bb07 (TCGA-99-8028.C5B3FD4E-8E81-4B8F-B38D-E2A6BBDED1EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).